Somatic mutation profile of tumor specimen TCGA-RS-A6TP-01A (aliquot TCGA-RS-A6TP-01A-12D-A34J-08) from TCGA case TCGA-RS-A6TP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.6 years (21,393 days).
Specimen TCGA-RS-A6TP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7da07474-c706-4814-a054-46c4fef8c508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RS-A6TP-10A (Blood Derived Normal), aliquot TCGA-RS-A6TP-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afb2204a-5e9b-4100-ad3a-c37079bd21e7

The open-access MAF lists 142 somatic variants for this specimen: 102 protein-altering or splice-affecting, 40 silent.
By variant classification: Missense Mutation 89, Silent 40, Nonsense Mutation 10, Frame Shift Ins 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1555950665, COSV101302370, COSV67863415; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99328634; called by muse, mutect2, varscan2
- ADIPOQ | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775692073, COSV100292101; called by muse, mutect2, varscan2
- AGGF1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 43/134 reads (32%) | catalogued as COSV100461598, COSV57229517; called by muse, mutect2, varscan2
- ALKBH7 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99831697; called by muse, mutect2, varscan2
- ATP10B | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100514368; called by muse, mutect2, varscan2
- C8orf34 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as COSV100297726; called by muse, mutect2, varscan2
- CAPRIN2 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1417692593, COSV99195436; called by muse, mutect2, varscan2
- CARD6 | c.859A>G p.K287E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV99620427; called by muse, mutect2, varscan2
- CCDC88A | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99709923; called by muse, mutect2, varscan2
- CDNF | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.425); catalogued as COSV101012361; called by muse, mutect2, varscan2
- CEP170 | c.1521G>C p.E507D | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV100316643; called by muse, mutect2, varscan2
- CLK2 | c.1447C>T p.R483W (on ENST00000368361 / NM_001294339.2; = p.R482W on NM_003993.4) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs200444017, COSV100226613; called by muse, mutect2, varscan2
- CNOT2 | c.732C>A p.N244K | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV57503166, COSV99972458; called by muse, mutect2, varscan2
- CP | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99223822; called by muse, mutect2, varscan2
- DDN | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100304944; called by muse, mutect2, varscan2
- DDX59 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 43/102 reads (42%) | catalogued as COSV100494440; called by muse, mutect2, varscan2
- DIP2C | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs370308829, COSV99790497; called by muse, mutect2, varscan2
- DMTN | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs781626631, COSV99741527; called by muse, mutect2, varscan2
- DNAH5 | c.11947C>T p.L3983F | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54208857; called by muse, mutect2, varscan2
- EHHADH | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746607247, COSV99213117; called by muse, mutect2, varscan2
- EPHA2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as rs757237384, COSV100626042; called by muse, mutect2, varscan2
- FREM2 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV99747402; called by muse, mutect2, varscan2
- GAL3ST4 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs200495131, COSV100385396, COSV100385638; called by muse, mutect2, varscan2
- GLUD2 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100046657; called by muse, mutect2, varscan2
- GPR45 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99306806; called by muse, mutect2
- H2AC17 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.455); catalogued as rs549660103, COSV100377509; called by muse, mutect2, varscan2
- H2AC8 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99773104; called by muse, mutect2, varscan2
- HAS3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs146829742; called by muse, mutect2, varscan2
- HECTD1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67947497, COSV67949500; called by muse, mutect2, varscan2
- HSPA12B | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99653869; called by muse, mutect2, varscan2
- ITGA8 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs142735096; called by muse, mutect2, varscan2
- ITGB3 | c.847G>C p.A283P | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD001900, COSV101457554; called by muse, mutect2, varscan2
- KCNH5 | c.1338G>C p.K446N | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100525669, COSV59774556; called by muse, mutect2, varscan2
- KCNV2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs367842869, COSV101172531; called by muse, varscan2
- KDM5C | c.4061G>A p.G1354E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100948878, COSV64763024; called by muse, mutect2, varscan2
- KMT2C | c.8993C>G p.S2998* | Nonsense Mutation (SNP) | VAF 123/150 reads (82%) | catalogued as COSV51435383; called by muse, mutect2, varscan2
- KMT2D | c.14059C>T p.Q4687* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99978507; called by muse, mutect2, varscan2
- KPNA1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.158); catalogued as COSV100724134; called by muse, mutect2, varscan2
- LCT | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as COSV99928829; called by muse, mutect2, varscan2
- LILRA5 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV56642618; called by muse, mutect2, varscan2
- LRRK1 | c.5431G>A p.D1811N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52621534, COSV99438177; called by muse, mutect2, varscan2
- MAP1B | c.6166A>G p.T2056A | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99701958; called by muse, mutect2, varscan2
- MATN1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs145452251; called by muse, mutect2, varscan2
- MLXIP | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100038513, COSV59836636; called by muse, mutect2, varscan2
- MPO | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1247303528, COSV99228517; called by muse, mutect2, varscan2
- MSH3 | c.2061G>T p.K687N | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV99432629; called by muse, mutect2, varscan2
- MTCH2 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100206862; called by muse, mutect2, varscan2
- MTSS2 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100116361; called by muse, mutect2, varscan2
- NEURL4 | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100223936; called by muse, varscan2
- NFU1 | c.81G>C p.K27N (on ENST00000410022 / NM_001002755.4; = p.K3N on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as COSV100361096, COSV58005709; called by muse, mutect2
- NIPBL | c.6187G>T p.E2063* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV56945564, COSV99239406, COSV99242997; called by muse, mutect2, varscan2
- NLRP8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149738419; called by muse, mutect2, varscan2
- NRAP | c.1945G>A p.D649N (on ENST00000359988 / NM_001322945.2; = p.D614N on NM_006175.4) | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as COSV100748325; called by muse, mutect2, varscan2
- NUDT14 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764223059, COSV59650378, COSV59650674; called by muse, mutect2, varscan2
- ODF2 | c.1075G>A p.E359K (on ENST00000434106 / NM_153433.2; = p.E335K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100654465; called by muse, mutect2, varscan2
- ODF3L1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV100150723; called by muse, mutect2, varscan2
- OLFM3 | c.202A>G p.T68A (on ENST00000338858 / NM_001288821.1; = p.T48A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58796705; called by muse, mutect2, varscan2
- OR5A1 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100118294; called by muse, mutect2, varscan2
- OTOA | c.1577G>T p.G526V (on ENST00000286149; = p.G512V on NM_144672.4) | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99623854; called by muse, mutect2, varscan2
- PARN | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100420734, COSV58367713; called by muse, mutect2, varscan2
- PCNX1 | c.2106T>G p.N702K | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.265); catalogued as COSV99454593; called by muse, mutect2, varscan2
- PDE8A | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051627; called by muse, mutect2
- PIDD1 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100204122; called by muse, mutect2, varscan2
- PITRM1 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs757064249, COSV99828404; called by muse, mutect2, varscan2
- PLEC | c.9031G>A p.D3011N (on ENST00000322810 / NM_201380.4; = p.D2901N on NM_000445.5) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100511903; called by muse, mutect2, varscan2
- PPEF1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 110/124 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100583612; called by muse, mutect2, varscan2
- PRKCA | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99434025; called by muse, mutect2, varscan2
- PROSER2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as COSV99508779; called by muse, mutect2, varscan2
- PROSER2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV53205329; called by muse, mutect2
- PRPF3 | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.173); catalogued as COSV100254578; called by muse, mutect2, varscan2
- PTGIS | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720735; called by muse, mutect2, varscan2
- RFTN1 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.584); catalogued as COSV100488962; called by muse, mutect2, varscan2
- SDK2 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.94); PolyPhen benign (0.036); catalogued as COSV101167082, COSV66196124; called by muse, mutect2, varscan2
- SEC24B | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV99493058; called by muse, mutect2, varscan2
- SEC24C | c.3214C>G p.L1072V | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100226588; called by muse, mutect2, varscan2
- SEMA4C | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100560773, COSV59691939; called by muse, mutect2, varscan2
- SESN2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV99455474; called by muse, mutect2, varscan2
- SKP2 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV99947913; called by muse, mutect2, varscan2
- SLC12A9 | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 110/124 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs764923874, COSV51931179, COSV99307589; called by muse, mutect2, varscan2
- SLC24A4 | c.834C>A p.F278L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV54110735; called by muse, mutect2, varscan2
- SPATA1 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs375737896, COSV99759644; called by muse, varscan2
- ST8SIA5 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 34/69 reads (49%) | PolyPhen probably damaging (1); catalogued as rs1205669470, COSV100164568; called by muse, mutect2, varscan2
- SUGP1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99894716; called by muse, mutect2, varscan2
- SUPT16H | c.2633C>G p.S878C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.975); catalogued as COSV99359708; called by muse, mutect2, varscan2
- TBX18 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.38); PolyPhen benign (0.413); catalogued as COSV100858458, COSV63737895; called by muse, mutect2, varscan2
- TENM3 | c.6261C>G p.I2087M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.477); catalogued as COSV101304944; called by muse, mutect2, varscan2
- TRAIP | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV100513084; called by muse, mutect2, varscan2
- TRIM38 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.118); catalogued as COSV100837550; called by muse, mutect2, varscan2
- TTN | c.102489G>C p.L34163F (on ENST00000591111; = p.L26739F on NM_003319.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | PolyPhen possibly damaging (0.626); catalogued as COSV100599420, COSV60173859; called by muse, mutect2, varscan2
- TTN | c.87387C>G p.I29129M (on ENST00000591111; = p.I21705M on NM_003319.4) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | PolyPhen benign (0.346); catalogued as COSV100599423; called by muse, mutect2, varscan2
- USP42 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs763843037, COSV100083967; called by muse, varscan2
- ZNF136 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV100677896; called by muse, mutect2, varscan2
- ZNF180 | c.766C>G p.Q256E | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV55421790, COSV55421879; called by muse, mutect2, varscan2
- ZNF208 | c.3403C>G p.H1135D | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101236888, COSV68105236; called by muse, mutect2, varscan2
- ZNF385B | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as COSV100415846; called by muse, mutect2, varscan2
- ZSCAN2 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100306851; called by muse, mutect2
- ARID1A | c.2190_2191dup p.G731Vfs*12 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- HDAC5 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- IGLV5-52 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAV9-2 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- WDR7 | c.3472_3478del p.E1158Sfs*3 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- AHNAK | c.17550G>C p.G5850= | Silent (SNP) | VAF 94/231 reads (41%) | catalogued as rs1486927859, COSV99946112; called by muse, mutect2, varscan2
- ALMS1 | c.2022C>T p.D674= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as rs374151754; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID1A | c.2187C>T p.P729= | Silent (SNP) | VAF 23/79 reads (29%) | called by mutect2, varscan2
- BLMH | c.42G>A p.L14= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as COSV99913052; called by muse, mutect2, varscan2
- CALCOCO2 | c.783G>A p.L261= | Silent (SNP) | VAF 51/93 reads (55%) | catalogued as COSV99363675; called by muse, mutect2, varscan2
- CBARP | c.1128C>T p.F376= (on ENST00000382477; = p.F356= on NM_152769.3) | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV99289409; called by muse, mutect2, varscan2
- CEP72 | c.765G>A p.T255= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs375299272; called by muse, mutect2, varscan2
- COL25A1 | c.105C>T p.A35= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV101211269; called by muse, mutect2, varscan2
- DAXX | c.747C>T p.T249= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs140033328; called by muse, mutect2, varscan2
- DHCR7 | c.1017C>T p.G339= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs774757811, COSV100831761; ClinVar: likely benign; called by muse, mutect2, varscan2
- ESYT3 | c.603C>T p.I201= | Silent (SNP) | VAF 84/365 reads (23%) | catalogued as COSV100004761; called by muse, mutect2, varscan2
- FCRL3 | c.582G>T p.L194= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV63843051; called by muse, mutect2, varscan2
- FMN2 | c.2169C>T p.L723= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs1214942228, COSV60453017; called by muse, mutect2, varscan2
- HIVEP3 | c.621C>T p.L207= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV99911763; called by muse, mutect2, varscan2
- HSPBP1 | c.960C>G p.L320= | Silent (SNP) | VAF 95/194 reads (49%) | catalogued as COSV55333974, COSV55334995; called by muse, mutect2, varscan2
- KANK3 | c.2175G>A p.Q725= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1353522651, COSV100035460; called by muse, mutect2
- KMT2B | c.1536C>T p.T512= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs375618290; called by muse, mutect2, varscan2
- LRIG2 | c.1020G>A p.L340= | Silent (SNP) | VAF 96/226 reads (42%) | catalogued as COSV100743051, COSV63162302; called by muse, mutect2, varscan2
- MFHAS1 | c.2862C>T p.T954= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as COSV99359296; called by muse, mutect2, varscan2
- MGAT1 | c.792C>T p.F264= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV100286555; called by muse, mutect2, varscan2
- MLXIP | c.1146C>T p.L382= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as COSV100038510; called by muse, mutect2, varscan2
- NLRC5 | c.2892C>G p.L964= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV52651875; called by muse, mutect2, varscan2
- NOS3 | c.3213C>T p.G1071= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV99871310; called by muse, mutect2
- NPC1L1 | c.1273C>T p.L425= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV56924724, COSV99203104; called by muse, mutect2, varscan2
- PARD6G | c.402C>T p.I134= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs765649568, COSV100783355; called by muse, varscan2
- PCDHGA7 | c.231G>C p.L77= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as rs1328104143, COSV99533130; called by muse, mutect2, varscan2
- PHF6 | c.303G>A p.R101= | Silent (SNP) | VAF 93/100 reads (93%) | catalogued as COSV100136289; called by muse, mutect2, varscan2
- PIK3AP1 | c.1554C>T p.D518= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs767542946, COSV100225587; called by muse, mutect2, varscan2
- R3HCC1L | c.1515G>A p.V505= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as rs1349578647, COSV100107169; called by muse, mutect2, varscan2
- RANBP6 | c.2922C>T p.V974= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV99424027, COSV99424356; called by muse, mutect2, varscan2
- RTEL1 | c.3403C>T p.L1135= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53929228, COSV99422804; called by muse, mutect2, varscan2
- SLC23A1 | c.660G>A p.L220= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100811905; called by muse, mutect2, varscan2
- SLC34A3 | c.222C>G p.L74= | Silent (SNP) | VAF 82/163 reads (50%) | catalogued as COSV100746632; called by muse, varscan2
- SLC6A12 | c.1506C>T p.L502= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as rs1332565157, COSV100675011, COSV100675163; called by muse, mutect2, varscan2
- SORL1 | c.4602C>T p.C1534= | Silent (SNP) | VAF 57/66 reads (86%) | catalogued as rs372370099; called by muse, mutect2, varscan2
- TMEM178A | c.567C>T p.L189= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV99931798; called by muse, mutect2, varscan2
- TRRAP | c.2370G>A p.L790= | Silent (SNP) | VAF 113/130 reads (87%) | catalogued as rs1554409690, COSV100722161; called by muse, mutect2, varscan2
- TRRAP | c.10803C>T p.C3601= (on ENST00000359863 / NM_001244580.1; = p.C3572= on NM_003496.3) | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs373922070, COSV100705488; called by muse, mutect2, varscan2
- VASN | c.684G>A p.L228= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99227309; called by muse, mutect2, varscan2
- ZNF671 | c.609C>T p.F203= | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as rs777587006, COSV100234874; called by muse, mutect2, varscan2
